Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A9SI, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A9SI-01A (Primary Tumor).

[page 1 of 6]
Collected
Ordered by:

FINAL DIAGNOSIS:

RADICAL CYSTECTOMY WITH ILEAL CONDUIT:

RIGHT DISTAL URETER (A):

FROZEN SECTION DIAGNOSIS:

- NO HIGH-GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT DISTAL URETER (B):

FROZEN SECTION DIAGNOSIS:

- NO HIGH-GRADE ATYPICA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

ANTERIOR VAGINAL WALL, BLADDER, UTERUS (C):

BLADDER:

- INVASIVE POORLY DIFFERENTIATED PAPILLARY UROTHELIAL CARCINOMA (3.5 CM GREATEST DIMENSION), GRADE 4/4, EXTENDING INTO DEEP MUSCULARIS PROPRIA OF LEFT POSTEROLATERAL BLADDER NECK AND APPROXIMATING WITHOUT INVOLVING PERIVESICAL SOFT TISSUE
- FOCUS OF LYMPHOVASCULAR SPACE INVASION SEEN
- TRIGONE / BLADDER NECK, MILD UROTHELIAL DYSPLASIA
- NO UROTHELIAL CARCINOMA IN SITU (FLAT LESION) IDENTIFIED
- RANDOM BLADDER, FOCAL EROSION AND CHRONIC INFLAMMATION WITH ASSOCIATED REACTIVE CHANGES
- FOREIGN BODY GIANT CELL REACTION IDENTIFIED, CONSISTENT WITH PREVIOUS BIOPSY SITE
- RESECTION MARGINS, FREE OF UROTHELIAL DYSPLASIA AND MALIGNANCY
- NO METASTATIC CARCINOMA IDENTIFIED IN TWO PERIVESICAL LYMPH NODES EXAMINED (0/2)

ANTERIOR VAGINAL WALL, UTERUS, RIGHT OVARY AND FALLOPIAN TUBE:

- ANTERIOR VAGINAL WALL, BENIGN SQUAMOUS MUCOSA WITH NO SIGNIFICANT HISTOPATHOLOGIC CHANGE
- CERVIX, NO SIGNIFICANT HISTOPATHOLOGIC CHANGE
- ENDOMETRIUM, ATROPHIC
- MYOMETRIUM, INTRAMURAL LEIOMYOMAS (3) EXHIBITING NO EVIDENCE OF ATYPIA OR MALIGNANCY
- RIGHT OVARY, BENIGN PHYSIOLOGICAL CHANGES
- RIGHT FALLOPIAN TUBE, NO SIGNIFICANT HISTOPATHOLOGIC CHANGES
- NO ATYPICAL, DYSPLASTIC OR MALIGNANT ELEMENTS IDENTIFIED

LEFT PARA AORTIC LYMPH NODES (D):

- NO METASTATIC CARCINOMA IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

LEFT COMMON ILIAC LYMPH NODES (E):

- NO METASTATIC CARCINOMA IDENTIFIED IN EIGHT LYMPH NODES EXAMINED (0/8)

RIGHT PARACAVAL LYMPH NODES (F):

- NO METASTATIC CARCINOMA IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)
- ENDOSALPINGIOSIS

RIGHT COMMON ILIAC LYMPH NODES (G):

- NO METASTATIC CARCINOMA IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

ICD 63
Carcinoma, urothelial papillary
Site Bladder NOS 813013
C67.9
path Bladder neck
C67.5
J23/26/14

[page 2 of 6]
Collected:

Ordered by:

RIGHT EXTERNAL ILIAC LYMPH NODES (H):

- NO METASTATIC CARCINOMA IDENTIFIED IN SIX LYMPH NODES EXAMINED (0/6)

RIGHT LYMPH NODE OF CLOQUET (I):

- NO METASTATIC CARCINOMA IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

RIGHT OBTURATOR / HYPOGASTRIC LYMPH NODES (J):

- NO METASTATIC CARCINOMA IDENTIFIED IN EIGHT LYMPH NODES EXAMINED (0/8)

LEFT EXTERNAL ILIAC LYMPH NODES (K):

- NO METASTATIC CARCINOMA IDENTIFIED IN EIGHT LYMPH NODES EXAMINED (0/8)

LEFT LYMPH NODE OF CLOQUET (L):

- NO METASTATIC CARCINOMA IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

LEFT OBTURATOR / HYPOGASTRIC LYMPH NODES (M):

- NO METASTATIC CARCINOMA IDENTIFIED IN NINE LYMPH NODES EXAMINED (0/9)

RIGHT PRESACRAL LYMPH NODES (N):

- NO METASTATIC CARCINOMA IDENTIFIED IN FIVE LYMPH NODES EXAMINED (0/5)

PRESACRAL LYMPH NODES (O):

- NO METASTATIC CARCINOMA IDENTIFIED IN EIGHT LYMPH NODES EXAMINED (0/8)

LEFT PRESACRAL LYMPH NODES (P):

- NO METASTATIC CARCINOMA IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

LEFT PROXIMAL URETER (Q):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT PROXIMAL URETER (R):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LYMPH NODE SUMMARY: NO METASTATIC CARCINOMA IDENTIFIED IN 75 LYMPH NODES
EXAMINED (0/75)

PATHOLOGIC TNM STAGE: pT2bN0MX

DIAGNOSIS COMMENT:

Representative tumor tissue (C11) is submitted for p53 assay by immunohistology, results of which will be issued in an addendum.

INTRAOPERATIVE DIAGNOSIS:

FROZEN SECTION DIAGNOSIS:

AFS: Right distal ureter:

- no high-grade atypia or tumor identified

BFS: Left distal ureter:

- no high-grade atypia or tumor identified

GROSS DESCRIPTION:

A: The specimen is received fresh from the O.R. and labeled "Right distal ureter F/S". It consists of a segment of right ureter measuring 0.4 cm in length and 0.4 cm in diameter. The entire specimen is submitted for frozen section diagnosis in

[page 3 of 6]
Temporary Copy

Ordered by

cassette AFS.

B: The specimen is received fresh from the O.R. and labeled "Left distal ureter". It consists of a segment of ureter measuring 0.4 cm in length and 0.3 cm in diameter. The entire specimen is submitted for frozen section diagnosis in cassette BFS.

C: The specimen is received fresh from the O.R. and labeled "Anterior vaginal wall, bladder, uterus". It consists of a cystectomy specimen with attached uterus and right adnexa and anterior vaginal wall. The entire specimen has overall measurements of 15.5 x 14.3 x 3.8 cm and weighs 290 grams. The peritoneum is pink-tan and smooth and shiny and measures 18 x 10.5 x < 0.1 cm. The bladder itself measures 7.5 x 7 x 3 cm. Palpation reveals a mass at the left lateral aspect of the bladder near the bladder neck, and the radial margin within this area is inked in black. The bladder is opened along the anterior bladder wall revealing a tumor in the left inferolateral wall measuring 3.5 x 3 x 2.1 cm, extending to the proximal aspect of the bladder neck. The tumor includes a pink to tan, firm, exophytic mass that measures 2.1 x 2 x 1.5 cm with an adjacent white-tan ulcer which measures 2.5 x 2 x 1 cm. Sectioning of the ulcerative area reveals a yellow-tan, firm, homogeneous cut surface. The tumor grossly appears to extend into the perivesical soft tissue and is located 0.5 cm from the inked radial margin. Additional sections show the tumor to be located 0.6 cm from the anterior vaginal wall. The tumor is located 1.3 cm below the left ureterovesical junction and 3.5 cm from the urethral margin. The uninvolved bladder wall measures 1.0 cm throughout and the remaining bladder mucosa is pink to tan and unremarkable with no other lesions identified. The urethra measures 2.5 cm in length and 2.3 cm in circumference and the urethral mucosa is unremarkable. The attached ureters are identified and opened. The right ureter measures 5.4 cm in length and 0.5 cm in circumference and the left distal ureter measures 1.8 cm in length and 0.6 cm in circumference. Grossly, the ureteral mucosa is unremarkable. The attached uterus and cervix measure 8 x 4.5 x 2 cm and have a tan, smooth, glistening serosal surface. The ectocervix measures 3.9 cm in diameter and shows a pink-tan, smooth, shiny epithelial surface, and the external os measures 1.5 cm. The uterus is bivalved. The endocervical canal measures 2.2 cm in length and 0.4 cm in diameter and is covered by a tan-gray granular mucosa. The endometrial cavity measures 1.2 x 3.4 cm and is covered by a thin endometrial strip measuring 0.1 cm in thickness. Serial sections show the myometrium to average 1.3 cm in thickness. A few small intramural leiomyomas are identified, one in the anterior wall measuring 0.4 cm in greatest dimension and two in the posterior myometrium measuring 0.4 and 0.6 cm. The right ovary measures 2.8 x 1 x 0.6 cm and has a tan-gray bosselated surface. Sectioning reveals a tan-gray, firm cut surface with no significant lesions identified. The right fallopian tube measures 7.4 cm in length and 0.5 cm in diameter and grossly is unremarkable. The left adnexa are not identified. The attached anterior vaginal wall measures 6 x 4.4 cm and is white to tan to pink and smooth and shiny with no significant lesions identified on the mucosal surface. Dissection and palpation of the perivesical fatty tissue reveals no lymph nodes. Representative sections are submitted in a total of 24 cassettes. The remaining portions of the case are received in formalin.

D: The specimen is received in formalin and labeled "Lt para aortic lymph nodes". It consists of a segment of yellow-tan-brown tissue measuring 3.2 x 1.7 x 0.9 cm. A large lymph node is identified measuring 2.2 cm in greatest dimension. The entire specimen is submitted in one cassette.

E: The specimen is received in formalin and labeled "Lt common iliac lymph nodes". It consists of a single segment of yellow-tan fatty tissue measuring 4.7 x 2 x 1 cm. Multiple lymph nodes are identified, the largest measuring 2 cm in greatest dimension. Representative sections are submitted in three cassettes.

F: The specimen is received in formalin and labeled "Right para caval LN". It

[page 4 of 6]
consists a single segment of tan-brown fatty tissue measuring 2.6 x 2 x 0.6 cm. A few lymph nodes are palpated, the largest measuring 1.5 cm in greatest dimension. The entire specimen is submitted in two cassettes.

G: The specimen is received in formalin and labeled "Rt common iliac LN". It consists of multiple segments of yellow-brown fatty tissue measuring in aggregate 4.9 x 3.2 x 0.5 cm. Multiple lymph nodes are identified, the largest measuring up to 3 cm in greatest dimension. The entire specimen is submitted in two cassettes.

H: The specimen is received in formalin and labeled "Rt external iliac LN". It consists of a segment of yellow-tan fatty tissue measuring 7.1 x 2.7 x 1 cm. A few lymph nodes are palpated, the largest measuring 3.4 cm in greatest dimension. Representative sections are submitted in three cassettes.

I: The specimen is received in formalin and labeled "Rt-LN of cloquet". It consists of a single segment of yellow fatty tissue measuring 1.7 x 1.7 x 1 cm. Palpating reveals a few lymph nodes. The entire specimen is submitted in one cassette.

J: The specimen is received in formalin and labeled "Rt obturator hypogastric LN". It consists of a large segment of yellow-tan fatty tissue measuring 7.3 x 3.3 x 1.2 cm. Multiple lymph nodes are palpated, the largest measuring up to 4 cm in greatest dimension. Representative sections are submitted in five cassettes.

K: The specimen is received in formalin and labeled "Left external iliac LN". It consists of multiple segments of yellow-tan fatty tissue aggregating to 7 x 4 x 0.9 cm. Multiple lymph nodes are palpated, the largest measuring up to 3.3 cm in greatest dimension. Representative sections are submitted

L: The specimen is received in formalin and labeled "L LN of cloquet". It consists of a single segment of yellow fatty tissue measuring 2.2 x 1.4 x 0.4 cm. A single lymph node is palpated measuring up to 1.2 cm in greatest dimension. The entire specimen is submitted in one cassette.

M: The specimen is received in formalin and labeled "Lt obturator hypogastric LN". It consists of multiple segments of yellow fatty tissue aggregating to 4.7 x 3.7 x 1.2 cm. Multiple lymph nodes are identified. The largest measuring up to 3 cm in greatest dimension. Representative sections are submitted in three cassettes.

N: The specimen is received in formalin and labeled "Rt pre sciatic LN". It consists of multiple fragments of yellow-tan fatty tissue aggregating to 3 x 2 x 1 cm. A few lymph nodes are palpated, the largest measuring up to 0.8 cm. The entire specimen is submitted in one cassette.

O: The specimen is received in formalin and labeled "Pre sacral LN". It consists of a single segment of yellow-tan-brown fibrofatty tissue measuring 6.3 x 4.8 x 0.4 cm. Multiple lymph nodes are palpated, the largest measuring up to 1.6 cm in greatest dimension. Representative sections are submitted in three cassettes.

P: The specimen is received in formalin and labeled "Lt pre sciatic LN". It consists of a few small fragments of yellow to brown fibrofatty connective tissue aggregating to 1.7 x 0.8 x 0.5 cm. A few possible lymph nodes are identified. The entire specimen is submitted in one cassette.

Q: The specimen is received in formalin and labeled "Left proximal ureter". It consists of a segment of ureter measuring 0.7 cm in length and 0.4 cm in diameter. The entire specimen is submitted in one cassette.

R: The specimen is received in formalin and labeled "Right proximal ureter". It consists of a segment of ureter measuring 0.9 cm in length and 0.4 cm in diameter.

[page 5 of 6]
The entire specimen is submitted in one cassette.

SECTIONS:

AFS: frozen section, right distal ureter F/S
BFS: frozen section, left distal ureter
C1: urethral margin
C2: anterior bladder wall, representative section
C3: right lateral bladder wall
C4: right ureterovesical junction
C5: posterior bladder wall
C6: bladder dome
C7: left lateral bladder wall
C8: left ureterovesical junction
C9: trigone
C10: urethra, representative section
C11: tumor, representative section
C12: tumor to anterior vaginal wall
C13: tumor to inked left lateral radial margin
C14,15: section of tumor including inked radial margin (section cut in half)
C16: tumor, representative section
C17: anterior vaginal wall, representative section
C18: anterior cervix with anterior vaginal wall
C19: posterior cervix
C20: full thickness, anterior endomyometrium including one leiomyoma
C21: full thickness, posterior endomyometrium including two leiomyomas
C22: right ovary and fallopian tube
C23: right perivesical fatty tissue
C24: left perivesical fatty tissue
D: left para-aortic lymph nodes all embedded
E1: left common iliac lymph nodes; largest lymph node, bisected
E2: one lymph node bisected
E3: lymph nodes
F1: right paracaval lymph node; largest lymph node, bisected
F2: entire remaining tissue
G1: right common iliac lymph node; largest lymph node, bisected
G2: entire remaining tissue
H1,2: right external iliac lymph node; largest lymph node, bisected
H3: lymph nodes
I: right lymph node of Cloquet all embedded
J1,2: right obturator hypogastric lymph node; largest lymph node, bisected
J3,4: one lymph node, bisected
J5: lymph nodes
K1,2: left external iliac lymph node; largest lymph node, bisected
K3: one lymph node, bisected
K4: lymph nodes
L: left lymph node of Cloquet all embedded
M1,2: left obturator hypogastric lymph node; largest lymph node, bisected
M3: lymph nodes
N: right presciatic lymph node all embedded
O1: presacral lymph node; one lymph node, bisected
O2: one lymph node, bisected
O3: one lymph node
P: left presciatic lymph node all embedded
Q: left proximal ureter all embedded
R: right proximal ureter all embedded

MICROSCOPIC DESCRIPTION:

A-B: See final microscopic-diagnosis.

[page 6 of 6]
C: Sections of bladder show an extensive poorly differentiated invasive papillary transitional cell carcinoma (C11-16), nuclear grade 4/4, located grossly at the left inferolateral bladder wall approximating the bladder neck and invading into deep muscularis propria and approaching but not involving the perivesical fatty tissue. The tumor is characterized by a large (grossly 2.1 x 2.0 x 1.5 cm) papillary proliferation of tumor cells with moderate to marked pleomorphism. The nuclear to cytoplasmic ratio is markedly increased in many cells, and the nuclei are round to oval, some showing large nucleoli. Numerous mitotic figures are seen as well as necrosis. The tumor deeply infiltrates into the muscularis propria with the closest inked radial margin located 0.4 cm from the tumor (C13). Lymphovascular invasion is identified (C11). The left ureterovesical junction is uninvolved. The tumor is located 0.6 cm from the anterior vaginal wall (C12). All resection margins are free of both malignancy and urothelial dysplasia. Additional sections of bladder show focal areas of erosion and mild to moderate chronic cystitis with lymphoid aggregates identified. Mild dysplasia is seen in the trigone but no foci of high-grade dysplasia or in situ carcinoma (flat lesion) are identified. In addition, a focal foreign body giant cell reaction is seen (C5) consistent with previous biopsy site.

Sections of anterior vaginal wall show benign squamous epithelium. Sections from the cervix show benign cervical glandular epithelium and the endometrium exhibits atrophic changes. Small intramural leiomyomas are identified. The right ovary shows benign physiological changes and the right fallopian tube is unremarkable. There is no evidence of atypia or malignancy.

Signed by:

ELECTRONIC SIGNATURE

POST-OPERATIVE DIAGNOSIS:

Same as preop

PRE-OPERATIVE DIAGNOSIS:

Bladder cancer

ORDERING PHYSICIAN:

Ordering Physician:

Source: NCI Genomic Data Commons file 27b74534-f529-4c39-89d4-63aeac50824d (TCGA-XF-A9SI.BB424BA5-5E43-410B-B27C-EFBBDE18DA00.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).